Gene-level copy-number profile of tumor specimen TCGA-ZF-A9RN-01A from TCGA case TCGA-ZF-A9RN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.9 years (24,795 days).
Specimen TCGA-ZF-A9RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fa36845f-36e4-4775-be7b-1de4a4691bfe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9RN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d526077-168d-473a-9277-ee8c2ee64ee3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 2,616; copy number 2: 26,977; copy number 3: 18,625; copy number 4: 10,104; copy number 5: 107; copy number 6: 1,181; copy number 7: 97; copy number 9: 27; copy number 36: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9RN-01A-11D-A42D-01): tumor purity 0.81, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:70,954,708–71,583,989, 1 gene (within-gene range 0–2): FOXP1.
- chr3:71,289,769–71,305,853, 1 gene: FOXP1-AS1.
- chr9:19,789,179–19,967,994, 5 genes: AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:21,384,255–23,672,387, 38 genes (within-gene range 0–5): IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,446 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,266,576–164,980,137, 18 genes, copy number 5 (within-gene range 4–5): NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:246,178,778–246,189,118, 2 genes, copy number 7: CHCHD4P5, RNU6-1283P.
- chr2:94,725,674–97,264,521, 114 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:54,122,547–56,468,467, 19 genes, copy number 6 (within-gene range 4–6): CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1, ERC2, AC025572.1, ERC2-IT1, MIR3938, RN7SKP45, RNA5SP133.
- chr3:90,184,634–103,241,230, 142 genes, copy number 6–7 (broad region; genes not listed).
- chr3:136,778,181–137,796,678, 15 genes, copy number 5: AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1.
- chr6:61,679,961–62,611,327, 5 genes, copy number 5 (within-gene range 4–5): KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr8:46,028,804–52,565,430, 94 genes, copy number 6–9 (within-gene range 4–15) (broad region; genes not listed).
- chr9:10,532,145–13,323,450, 25 genes, copy number 5: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1.
- chr9:13,406,380–13,488,125, 1 gene, copy number 5: LINC01235.
- chr9:23,632,106–24,088,051, 9 genes, copy number 5: SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr10:44,712–21,293,011, 344 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr10:21,217,891–38,783,108, 328 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr15:19,878,555–24,823,365, 182 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr15:24,675,775–24,683,393, 1 gene, copy number 6: NPAP1.
- chr15:57,706,695–59,372,871, 49 genes, copy number 5–7: POLR2M, AC090651.1, ALDH1A2, AC012653.1, AC012653.2, AC025431.1, AQP9, MTCO3P23, MTND3P12, AC066616.2, MTND5P32, MTCYBP23, AC066616.1, LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2, AC018904.1, ADAM10, HMGB1P51, AC091046.1, HSP90AB4P, RN7SKP95, AC091046.2, AC090515.6, AC090515.3, SNORD3P1, AC090515.2, MINDY2, AC090515.5, AC090515.4, ZNF444P1, RNF111, AC090515.1, SLTM, AC025918.1, AC025918.2, AC092757.1, CCNB2, AC092757.3, AC092757.2, MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1, RNU6-212P, AC092868.2.
- chr21:10,328,411–16,815,688, 98 genes, copy number 6–36 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,577. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
